Somatic mutation profile of tumor specimen TCGA-24-2295-01A (aliquot TCGA-24-2295-01A-01W-0799-08) from TCGA case TCGA-24-2295, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 69.6 years (25,416 days).
Specimen TCGA-24-2295-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6761d2ef-07d1-43df-bb67-7857b91c5577.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-2295-10A (Blood Derived Normal), aliquot TCGA-24-2295-10A-01W-0799-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b774cae-4138-4e1f-92c8-91d8942c5c9f

The open-access MAF lists 89 somatic variants for this specimen: 68 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 20, Nonsense Mutation 4, 3'UTR 1, Splice Site 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.713G>A p.C238Y | Missense Mutation (SNP) | VAF 188/238 reads (79%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882005, CM034930, COSV52661646, COSV52706816, COSV52804264; ClinVar: likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- ABRA | c.1055T>C p.M352T | Missense Mutation (SNP) | VAF 141/719 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV100357557; called by muse, mutect2, varscan2
- ADCY10 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 47/298 reads (16%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); catalogued as COSV100896842; called by muse, mutect2, varscan2
- ALDH1B1 | c.419A>G p.D140G | Missense Mutation (SNP) | VAF 41/159 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV100890939; called by muse, mutect2, varscan2
- ANKRD27 | c.1531G>A p.V511M | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs768131117, COSV60131477; called by muse, mutect2
- ASXL2 | c.3995A>G p.N1332S | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.233); catalogued as rs775329935, COSV99710244; called by muse, mutect2, varscan2
- BCL9 | c.2516G>A p.R839H | Missense Mutation (SNP) | VAF 52/499 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs371225184, COSV52344790, COSV52347993; called by muse, mutect2, varscan2
- BFSP1 | c.1372C>G p.P458A | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); catalogued as COSV100925367; called by muse, mutect2, varscan2
- CADPS | c.2059C>T p.R687C | Missense Mutation (SNP) | VAF 95/368 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs182039177, COSV51865292; called by muse, mutect2, varscan2
- CCDC191 | c.2271G>A p.W757* | Nonsense Mutation (SNP) | VAF 758/1437 reads (53%) | catalogued as COSV99878248; called by muse, mutect2, varscan2
- CNOT10 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs373173755; called by muse, mutect2
- DIP2C | c.1894G>A p.D632N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs754698560, COSV55181011, COSV99791628; called by muse, mutect2
- DNMT3B | c.481C>G p.P161A | Missense Mutation (SNP) | VAF 58/517 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.021); catalogued as COSV52420442, COSV99141435; called by muse, mutect2, varscan2
- DSG3 | c.37G>T p.A13S | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.001); catalogued as COSV99934150; called by muse, mutect2, varscan2
- ENTPD3 | c.1169C>A p.T390N | Missense Mutation (SNP) | VAF 44/153 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.084); catalogued as COSV100088682; called by muse, mutect2, varscan2
- FAM135A | c.905T>C p.L302P (on ENST00000370479 / NM_001351599.1; = p.L285P on NM_020819.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.657); catalogued as COSV99525777; called by muse, mutect2, varscan2
- FCHSD2 | c.2177G>A p.R726Q | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.968); catalogued as rs757495469, COSV100238386; called by muse, mutect2, varscan2
- FOXA2 | c.590G>T p.R197L (on ENST00000377115 / NM_153675.3; = p.R203L on NM_021784.5) | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.31); catalogued as rs372773557, COSV101008356; called by muse, mutect2, varscan2
- FRYL | c.5930G>T p.R1977I | Missense Mutation (SNP) | VAF 33/266 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.223); catalogued as COSV99976886; called by muse, mutect2, varscan2
- GABRA1 | c.1088A>C p.K363T | Missense Mutation (SNP) | VAF 40/192 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.049); catalogued as COSV99195906; called by muse, mutect2, varscan2
- GUCY2C | c.1345G>A p.V449I | Missense Mutation (SNP) | VAF 19/194 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs375918996; called by muse, mutect2, varscan2
- H4C8 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 62/227 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.228); catalogued as COSV99175476; called by muse, mutect2, varscan2
- HMCN1 | c.5062A>G p.I1688V | Missense Mutation (SNP) | VAF 32/186 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV99629166; called by muse, mutect2, varscan2
- HSD3B2 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs756060240, COSV65592700; called by muse, mutect2, varscan2
- IGSF1 | c.3433G>A p.A1145T | Missense Mutation (SNP) | VAF 28/987 reads (3%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.98); catalogued as COSV100812077; called by muse, mutect2
- KCNG1 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV100857080, COSV100857084; called by muse, mutect2, varscan2
- KCNH7 | c.2812A>C p.I938L | Missense Mutation (SNP) | VAF 103/539 reads (19%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as COSV100147990; called by muse, mutect2, varscan2
- KIF16B | c.3081G>T p.M1027I | Missense Mutation (SNP) | VAF 89/684 reads (13%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs569473421, COSV100734275; called by muse, mutect2, varscan2
- LGALS1 | c.378C>G p.D126E | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV99313769; called by muse, mutect2
- LRRC7 | c.2417G>T p.W806L (on ENST00000651989 / NM_001370785.2; = p.W773L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/600 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50491806, COSV99226818; called by muse, mutect2
- MAGED1 | c.1774C>T p.R592C | Missense Mutation (SNP) | VAF 43/313 reads (14%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100431574; called by muse, mutect2, varscan2
- MECOM | c.1888G>T p.A630S (on ENST00000468789 / NM_001105078.4; = p.A818S on NM_004991.4) | Missense Mutation (SNP) | VAF 11/240 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as COSV99244695; called by muse, mutect2
- MED24 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 72/404 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs778904723, COSV100673190; called by muse, mutect2, varscan2
- MIDEAS | c.2164C>T p.R722W | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1165071367, COSV54095474; called by muse, mutect2, varscan2
- MUC16 | c.8969A>G p.E2990G | Missense Mutation (SNP) | VAF 12/452 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.006); catalogued as COSV101199902; called by muse, mutect2
- MYBPC1 | c.2249A>G p.D750G (on ENST00000550270 / NM_206820.2; = p.D775G on NM_002465.4) | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV100637985; called by muse, mutect2, varscan2
- NAALADL2 | c.1178C>T p.S393L | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs779860489, COSV101380127; called by muse, mutect2, varscan2
- NCAPD3 | c.1909G>T p.E637* | Nonsense Mutation (SNP) | VAF 49/212 reads (23%) | catalogued as COSV101599362; called by muse, mutect2, varscan2
- NSUN3 | c.270G>T p.K90N | Missense Mutation (SNP) | VAF 172/227 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as COSV100113278; called by muse, mutect2, varscan2
- NUP62CL | c.512A>G p.D171G | Missense Mutation (SNP) | VAF 147/1038 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100991019; called by muse, mutect2, varscan2
- NWD1 | c.2128C>T p.R710* | Nonsense Mutation (SNP) | VAF 20/81 reads (25%) | catalogued as rs777897918, COSV100342580; called by muse, mutect2
- OR11A1 | c.555C>A p.F185L | Missense Mutation (SNP) | VAF 33/181 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101010707, COSV65820678; called by muse, mutect2, varscan2
- OR4Q3 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 32/323 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100057025; called by muse, mutect2, varscan2
- OR9G4 | c.829T>C p.F277L | Missense Mutation (SNP) | VAF 11/241 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV100265125; called by muse, mutect2
- PCDHB15 | c.1815G>C p.Q605H | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.329); catalogued as COSV99178916; called by muse, mutect2, varscan2
- PCMTD2 | c.952C>T p.R318W | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.251); catalogued as rs750037182, COSV100204041; called by muse, mutect2
- PIGU | c.297C>G p.I99M | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.521); catalogued as COSV54163766, COSV99466418; called by muse, mutect2, varscan2
- PNLIP | c.487G>A p.V163M | Missense Mutation (SNP) | VAF 25/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs200040515, COSV100981798; called by muse, mutect2, varscan2
- PRSS35 | c.1219G>A p.D407N | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs776819854, COSV63800274; called by muse, mutect2, varscan2
- PUM2 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.687); catalogued as COSV100163632; called by muse, mutect2, varscan2
- PXDC1 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.995); catalogued as COSV66661339; called by muse, mutect2, varscan2
- RAPGEF2 | c.3724G>T p.A1242S | Missense Mutation (SNP) | VAF 47/808 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV100031134; called by muse, mutect2
- RAPGEF6 | c.2876T>G p.L959R | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.971); catalogued as COSV99726432; called by muse, mutect2, varscan2
- RNF182 | c.37C>T p.Q13* | Nonsense Mutation (SNP) | VAF 146/422 reads (35%) | catalogued as COSV101337892; called by muse, mutect2, varscan2
- SEPTIN14 | c.1144A>C p.K382Q | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.196); catalogued as COSV101193326; called by muse, mutect2, varscan2
- SHTN1 | c.712-2A>T p.X238_splice | Splice Site (SNP) | VAF 35/144 reads (24%) | catalogued as COSV99598903; called by muse, mutect2, varscan2
- SOGA1 | c.2924A>G p.N975S | Missense Mutation (SNP) | VAF 124/292 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.082); catalogued as rs754144105, COSV99412435; called by muse, mutect2, varscan2
- SPA17 | c.385A>G p.I129V | Missense Mutation (SNP) | VAF 77/323 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs374299319, COSV99907118; called by muse, mutect2, varscan2
- SPATA5 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs777343800, COSV99915430; called by muse, mutect2, varscan2
- SYNE1 | c.20599C>T p.L6867F (on ENST00000367255 / NM_182961.4; = p.L6796F on NM_033071.3) | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99563789; called by muse, mutect2, varscan2
- TTPA | c.629T>C p.I210T | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs753949967, COSV99478511; called by muse, mutect2
- VCAM1 | c.1000A>G p.T334A | Missense Mutation (SNP) | VAF 16/155 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.39); catalogued as COSV99658544; called by muse, mutect2, varscan2
- YLPM1 | c.4862G>T p.G1621V | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.009); catalogued as COSV53114891, COSV99459628; called by muse, mutect2
- ZBTB45 | c.643G>A p.D215N | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV54020976, COSV99564350; called by muse, mutect2
- ZFP64 | c.842A>G p.H281R | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99402469; called by muse, mutect2, varscan2
- ZNF479 | c.280A>T p.T94S | Missense Mutation (SNP) | VAF 21/217 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.049); catalogued as COSV100482741; called by muse, mutect2, varscan2
- NUP98 | c.1484_1498del p.A495_A499del | In Frame Del (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel
- ZNF449 | c.724dup p.M242Nfs*59 | Frame Shift Ins (INS) | VAF 16/104 reads (15%) | called by mutect2, varscan2
- ADNP2 | c.2782C>T p.L928= | Silent (SNP) | VAF 32/130 reads (25%) | catalogued as rs1442821651, COSV100080846, COSV51541885; called by muse, mutect2, varscan2
- AHNAK | c.12915A>G p.V4305= | Silent (SNP) | VAF 153/703 reads (22%) | catalogued as rs1159198584, COSV99947403; called by muse, mutect2, varscan2
- ANO4 | c.1509C>T p.I503= (on ENST00000392977 / NM_001286615.2; = p.I468= on NM_178826.4) | Silent (SNP) | VAF 19/139 reads (14%) | catalogued as rs745433802, COSV100151947; called by muse, mutect2, varscan2
- ARFGEF2 | c.2673G>T p.R891= | Silent (SNP) | VAF 120/454 reads (26%) | catalogued as COSV100904251; called by muse, mutect2, varscan2
- ARHGAP21 | c.4881C>A p.I1627= | Silent (SNP) | VAF 20/617 reads (3%) | catalogued as COSV100256193; called by muse, mutect2
- BEST1 | c.1719T>C p.P573= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as COSV99861296; called by muse, mutect2, varscan2
- BLK | c.1155C>T p.I385= | Silent (SNP) | VAF 20/20 reads (100%) | catalogued as rs770398225, COSV52050328; called by muse, mutect2, varscan2
- CABP4 | c.408C>G p.A136= | Silent (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100351521, COSV56886876; called by muse, mutect2
- DHX34 | c.1827A>T p.A609= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as COSV100169573; called by muse, mutect2, varscan2
- GIMAP8 | c.303T>A p.I101= | Silent (SNP) | VAF 108/603 reads (18%) | catalogued as COSV100217530; called by muse, mutect2, varscan2
- HOXC10 | c.45C>G p.P15= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as COSV100329077; called by muse, mutect2, varscan2
- JADE3 | c.1782G>A p.P594= | Silent (SNP) | VAF 33/266 reads (12%) | catalogued as rs976995798, COSV99509866; called by muse, mutect2, varscan2
- MBNL3 | c.660C>A p.I220= | Silent (SNP) | VAF 80/536 reads (15%) | catalogued as COSV100898470; called by muse, mutect2, varscan2
- NR1I3 | c.207G>A p.Q69= | Silent (SNP) | VAF 17/557 reads (3%) | catalogued as rs1303630327, COSV100915665; called by muse, mutect2
- OR6N1 | c.675G>A p.V225= | Silent (SNP) | VAF 112/677 reads (17%) | catalogued as rs1558031266, COSV100625171; called by muse, mutect2, varscan2
- PATJ | c.1836T>C p.L612= | Silent (SNP) | VAF 185/776 reads (24%) | catalogued as COSV100334178; called by muse, mutect2, varscan2
- PHOSPHO2 | c.207G>T p.V69= | Silent (SNP) | VAF 9/179 reads (5%) | catalogued as COSV99775804; called by muse, mutect2
- RAP1B | c.189A>G p.Q63= | Silent (SNP) | VAF 55/423 reads (13%) | catalogued as rs989482978, COSV99164901; called by muse, mutect2, varscan2
- SMG6 | c.1788C>T p.S596= | Silent (SNP) | VAF 22/360 reads (6%) | catalogued as COSV99558168; called by muse, mutect2
- TACC2 | c.6699G>A p.T2233= (on ENST00000334433; = p.T311= on NM_006997.4) | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs748058471, COSV99587061; called by muse, mutect2, varscan2
- CPLANE1 | c.*3340G>T | 3'UTR (SNP) | VAF 18/156 reads (12%) | catalogued as COSV99950513; called by muse, mutect2, varscan2
